TARGET case TARGET-20-PAYKGB-Sorted-CD34neg-Myeloid-Mono — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/16b15a10-6a10-4a90-8bf8-aa7b0057536e

Biospecimens (1 sample)
- Sample TARGET-20-PAYKGB-Sorted-CD34neg-Myeloid-Mono-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
